Surgical pathology report (de-identified scan), TCGA case TCGA-36-2537, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2537-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

TCGA - 36 - 2537

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

Hysterectomy, bilateral salpingo-oophorectomy, omentectomy and pelvic/peritoneal washing specimens showing:

1. High-grade serous carcinoma of left ovary with implants of metastatic serous carcinoma to right ovary, fallopian tubes, serosal surface of the uterus and omentum.
2. Benign uterine leiomyomas.
3. Proliferative endometrium.
4. Benign endo- and exocervical mucosa.
5. Peritoneal fluid (cytology specimen is positive for serous carcinoma.
6. Please see Comment.

Final Diagnosis Comment:

This unusual tumour shows both high-grade and low-grade architectural growth patterns; however, on closer examination it has a high mitotic rate throughout and is

[page 2 of 3]
best classified as high-grade serous carcinoma. The tumour involves both ovaries, the serosal surface of the uterus and omentum. No fallopian tube mucosal involvement is identified.

Clinical History as Provided by Submitting Physician:

with pelvic mass

Cytology

A. Uterus, cervix, bilateral tubes and ovaries

B. Omentum

Specimens Received:

A: uterus + cervix + bilateral tubes + ovaries

B: omentum

Gross Description:

Two specimens are received, both labelled with the patient's demographics. Peritoneal fluid washing for cytology (cytology #) is also received.

Specimen A is labelled UTERUS, CERVIX, BILATERAL TUBES AND OVARIES. It consists of a bilateral salpingo-oophorectomy and a total hysterectomy specimen. The left ovary is completely replaced by a tan complex cystic mass with solid and papillary areas measuring approximately 15 cm in diameter. Multiple tumour implants are identified on the serosal surface of this cyst. The left fallopian tube measures 4 cm in length and 1 cm in diameter. Its serosal surface is also involved by the tumour implants, with possible mural and luminal involvement. The right ovary measures 2.5 x 2.2 x 5.5 cm, and it is partially replaced by the same tumour, with serosal implants identified. The uterine body measures 5.6 x 5 x 4 cm. Its posterior surface/cul-de-sac is extensively involved by tumour implants. The anterior surface is also involved, albeit less extensively. The endometrium appears grossly unremarkable. Several leiomyomata, measuring up to 1.2 cm, are identified. The cervix measures 4.5 cm in length and 4.5 cm in diameter. It appears grossly unremarkable. The serosal surfaces of the right and left adnexa and uterus are inked blue. The resection margins are inked black.

Representative sections are submitted as follows:

A1-A2 -sections obtained during the frozen section

A3-A8 -representative sections of the left ovarian mass

A9 -left fallopian tube

A10-A12 -right ovary

A13 -right fallopian tube

[page 3 of 3]
A14-A17 -anterior endomyometrium, from superior to inferior, with A15-A16 being from the same level

A18 -anterior junction of the lower uterine segment and endocervix

A19 -anterior junction of the endocervix and ectocervix

A20-A23 -posterior endomyometrium, from superior to inferior, with A20-A21 from the same level and A22-A23 from the same level

A24-A25 -posterior junction of the lower uterine segment and endocervix, with A25 being from cul-de-sac

A26 -posterior junction of the endocervix and ectocervix

Specimen B is labelled OMENTUM. It consists of a fibrofatty tissue measuring 13 x 6 x 3.5 cm. Multiple tumour deposits are identified in this specimen. Representative sections are submitted as B1 to B4.

Intraoperative Consultation:

FSA/1,2

Gross Description: Large left sided mass, cystic, multiple with solid and papillary excrescences with serosal implants right side adnexal and elsewhere on uterus. F/S: cyst (L) -A1, opposite side -A2.

Provisional Diagnosis: Serous carcinoma, variably differentiated.

Source: NCI Genomic Data Commons file 730cc773-8881-4e39-ab82-67dc50566443 (TCGA-36-2537.9B122691-9140-439E-9EF6-16701081B905.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).